Somatic mutation profile of tumor specimen 2f8b02e4-1848-4abc-a95e-dd9eb5 (aliquot 2f8b02e4-1848-4abc-a95e-dd9eb5_D6) from CPTAC case 05CO033, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC.
Specimen 2f8b02e4-1848-4abc-a95e-dd9eb5: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6773af84-735e-412f-9ee6-832b9b790c30.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 2db0e2fa-e434-4751-924f-c55ad3 (Blood Derived Normal), aliquot 2db0e2fa-e434-4751-924f-c55ad3_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/44b81b87-6a7f-47d8-bbdf-086706dc6dfd

The open-access MAF lists 126 somatic variants for this specimen: 89 protein-altering or splice-affecting, 30 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 30, Intron 5, Nonsense Mutation 5, Splice Region 2, Frame Shift Del 2, Frame Shift Ins 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 27/264 reads (10%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.1723G>A p.G575R | Missense Mutation (SNP) | VAF 42/485 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs797044875, CM162169, COSV62690253; ClinVar: likely pathogenic; called by muse, mutect2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 122/500 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMAD2 | c.1391C>G p.S464* | Nonsense Mutation (SNP) | VAF 83/401 reads (21%) | hotspot (GDC flag); catalogued as COSV50992836, COSV50992894, COSV50993280; called by muse, mutect2, varscan2
- A2M | c.4365G>A p.T1455= | Splice Region (SNP) | VAF 42/181 reads (23%) | catalogued as rs1247896058; called by muse, mutect2, varscan2
- ACTR10 | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs763599120, COSV54297362; called by muse, mutect2, varscan2
- ACVRL1 | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 73/412 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as CM040655, COSV101187810, COSV66360942; called by muse, mutect2, varscan2
- APC | c.2287G>T p.E763* | Nonsense Mutation (SNP) | VAF 51/405 reads (13%) | catalogued as CM106354, COSV57350231; called by muse, mutect2, varscan2
- BRINP1 | c.1556G>T p.R519L | Missense Mutation (SNP) | VAF 52/420 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.931); catalogued as COSV56292199; called by mutect2, varscan2
- CFAP61 | c.2251G>T p.A751S | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.203); catalogued as COSV55649771; called by muse, mutect2
- COL5A1 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 36/557 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as rs549951334; called by muse, mutect2
- CTNNA2 | c.2237A>G p.K746R | Missense Mutation (SNP) | VAF 9/217 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.12); catalogued as rs1046015109; called by muse, mutect2
- DCC | c.866T>C p.L289S | Missense Mutation (SNP) | VAF 54/531 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.904); catalogued as rs1025818300; called by muse, mutect2, varscan2
- DIS3L | c.1132C>T p.R378* (on ENST00000319212 / NM_001143688.3; = p.R295* on NM_133375.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 12/135 reads (9%) | catalogued as rs893215526, COSV59911391; called by muse, mutect2
- FAM163A | c.14C>T p.T5M | Missense Mutation (SNP) | VAF 14/189 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs906615434; called by muse, mutect2
- FLT4 | c.2657C>T p.T886M | Missense Mutation (SNP) | VAF 25/300 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771222400, COSV56103258; called by muse, mutect2
- FYB1 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 31/305 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs773904224, COSV60951888; called by muse, mutect2, varscan2
- GABRA5 | c.991G>A p.V331I | Missense Mutation (SNP) | VAF 33/385 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as rs750382923, COSV59477919; called by muse, mutect2
- GABRR2 | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 48/456 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140140640; called by muse, mutect2, varscan2
- HOXD12 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 46/424 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1370140832; called by muse, mutect2, varscan2
- IGFN1 | c.1153G>A p.G385R | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs770358996; called by muse, mutect2, varscan2
- IRX5 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 26/290 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV58058885; called by muse, mutect2
- KDM3B | c.3188G>A p.R1063Q | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.087); catalogued as rs758977082, COSV58691835; called by muse, mutect2, varscan2
- LAMA5 | c.1273G>A p.V425I | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.024); catalogued as rs371375888; called by muse, mutect2, varscan2
- LAMC3 | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 102/864 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as rs770671723, COSV63088161; called by muse, mutect2, varscan2
- LDLR | c.2264C>T p.A755V | Missense Mutation (SNP) | VAF 35/364 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as CD118072; called by muse, mutect2
- LRFN4 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.487); catalogued as rs1158223624; called by muse, mutect2, varscan2
- LRP1B | c.13525C>T p.L4509F | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV67192488; called by muse, mutect2
- MAP1A | c.6343C>T p.R2115W | Missense Mutation (SNP) | VAF 26/217 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.629); catalogued as rs775209108; called by muse, mutect2, varscan2
- MGAT4C | c.978G>T p.K326N | Missense Mutation (SNP) | VAF 37/398 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59829520, COSV59838193; called by muse, mutect2
- OR6N2 | c.266A>C p.K89T | Missense Mutation (SNP) | VAF 15/358 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV59413513; called by muse, mutect2
- OR8H2 | c.167T>C p.L56P | Missense Mutation (SNP) | VAF 31/304 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57943415; called by muse, mutect2, varscan2
- OTUD4 | c.1172C>T p.A391V (on ENST00000447906 / NM_001366057.1; = p.A326V on NM_001102653.1) | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs199880420; called by muse, mutect2
- PCDHGB2 | c.1474G>A p.V492I | Missense Mutation (SNP) | VAF 57/560 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.08); catalogued as rs1259552110, COSV54044139; called by muse, mutect2, varscan2
- PLXND1 | c.3820G>A p.V1274M | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs748190414; called by muse, mutect2
- POU3F4 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 73/346 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as rs760582733; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRR23A | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.886); catalogued as rs1315465692; called by muse, mutect2, varscan2
- PRSS57 | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 28/264 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs201490930; called by muse, mutect2
- RDX | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 29/340 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); catalogued as rs17854426; called by muse, mutect2
- RNF32 | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 48/540 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs770700325, COSV58731739; called by muse, mutect2
- RPGRIP1L | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 42/339 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as rs1168346867; called by muse, mutect2, varscan2
- RYR2 | c.235C>A p.Q79K | Missense Mutation (SNP) | VAF 32/346 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs368014180; called by muse, mutect2
- SBNO1 | c.2939G>A p.R980H (on ENST00000420886; = p.R979H on NM_018183.5) | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57344340; called by muse, mutect2, varscan2
- SEMA6D | c.671T>C p.L224P | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60381371; called by muse, mutect2
- SHANK1 | c.4975G>A p.A1659T | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1324075212; called by muse, mutect2, varscan2
- SPTA1 | c.5195A>G p.K1732R | Missense Mutation (SNP) | VAF 32/473 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV100934623, COSV100935599; called by muse, mutect2
- TNXB | c.4705G>A p.D1569N (on ENST00000647633; = p.D1322N on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/244 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs1280340355, COSV100925874; called by muse, mutect2, varscan2
- TPH2 | c.1085T>C p.I362T | Missense Mutation (SNP) | VAF 42/395 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs779288303; called by muse, mutect2, varscan2
- TTN | c.86197G>C p.V28733L (on ENST00000591111; = p.V21309L on NM_003319.4) | Missense Mutation (SNP) | VAF 14/396 reads (4%) | PolyPhen benign (0.003); catalogued as COSV100621452; called by muse, mutect2
- TULP2 | c.1405C>T p.R469W | Missense Mutation (SNP) | VAF 31/233 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs760643540, COSV55479325; called by muse, mutect2, varscan2
- UGT2A3 | c.1049G>A p.R350Q | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs545451272; called by muse, mutect2, varscan2
- VCAN | c.7552G>A p.G2518S | Missense Mutation (SNP) | VAF 64/647 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs371161146; called by muse, mutect2
- VWF | c.5287C>T p.R1763W | Missense Mutation (SNP) | VAF 48/530 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as rs763126601; called by muse, mutect2
- ZNF804B | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 32/341 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs773501845, COSV100301188; called by muse, mutect2
- ZNF835 | c.1343G>T p.C448F | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1388771715; called by muse, mutect2
- ZNF879 | c.255C>T p.L85= | Splice Region (SNP) | VAF 18/151 reads (12%) | catalogued as rs566204932; called by muse, mutect2, varscan2
- ZSWIM1 | c.1115A>G p.H372R | Missense Mutation (SNP) | VAF 30/302 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs769084724; called by muse, mutect2, varscan2
- CCDC168 | c.618del p.N206Kfs*19 | Frame Shift Del (DEL) | VAF 30/314 reads (10%) | called by mutect2, pindel
- CNR2 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.211); called by muse, mutect2
- DENND1A | c.988G>T p.E330* | Nonsense Mutation (SNP) | VAF 16/160 reads (10%) | called by mutect2, varscan2
- DNAJB13 | c.550G>A p.V184M | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DTX4 | c.1163A>C p.K388T | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.474); called by muse, mutect2
- FAT4 | c.701T>G p.L234R | Missense Mutation (SNP) | VAF 20/271 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- FPGT | c.1587C>G p.N529K | Missense Mutation (SNP) | VAF 13/323 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.094); called by muse, mutect2
- GAS2L3 | c.1746T>G p.N582K | Missense Mutation (SNP) | VAF 68/527 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GIMAP8 | c.1540G>A p.V514I | Missense Mutation (SNP) | VAF 36/338 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GPR132 | c.278G>A p.G93D | Missense Mutation (SNP) | VAF 39/318 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- KANSL1L | c.245dup p.L82Ffs*5 | Frame Shift Ins (INS) | VAF 34/221 reads (15%) | called by mutect2, varscan2
- KCNMA1 | c.1943C>A p.P648H | Missense Mutation (SNP) | VAF 40/380 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC4C | c.473del p.N158Tfs*20 | Frame Shift Del (DEL) | VAF 36/400 reads (9%) | called by mutect2, pindel
- MUC17 | c.5967T>G p.S1989R | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- NSDHL | c.1096T>G p.F366V | Missense Mutation (SNP) | VAF 27/252 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- NTN1 | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2
- NYNRIN | c.4123C>T p.L1375F | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.089); called by muse, mutect2
- OR10J5 | c.306C>A p.F102L | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.176); called by muse, mutect2
- OR6K6 | c.52T>A p.F18I | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OR8G2P | c.127T>G p.L43V | Missense Mutation (SNP) | VAF 26/331 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.04); called by muse, mutect2
- OSBPL10 | c.557G>A p.S186N | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.517); called by muse, mutect2
- PCDHGA5 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 40/402 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.023); called by muse, mutect2
- PLS1 | c.1120A>G p.T374A | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.098); called by muse, mutect2
- POFUT1 | c.248T>A p.L83H | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.633); called by muse, varscan2
- POM121L2 | c.1988A>G p.D663G | Missense Mutation (SNP) | VAF 58/491 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ROBO2 | c.1757G>A p.R586Q | Missense Mutation (SNP) | VAF 58/454 reads (13%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- RYR3 | c.6718C>G p.L2240V | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEMG1 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.046); called by muse, mutect2
- SLC6A14 | c.1557G>T p.W519C | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TIAM1 | c.16A>G p.S6G | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- TMEM132D | c.1510G>C p.V504L | Missense Mutation (SNP) | VAF 10/205 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.909); called by muse, mutect2
- TRIM49 | c.881A>C p.E294A | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.078); called by muse, mutect2
- A1BG | c.366G>A p.S122= | Silent (SNP) | VAF 14/170 reads (8%) | catalogued as rs147168349; called by muse, mutect2
- ADAMTS2 | c.1428G>A p.P476= | Silent (SNP) | VAF 28/306 reads (9%) | catalogued as rs374288519; ClinVar: uncertain significance; called by muse, mutect2
- AHNAK2 | c.6060C>T p.A2020= | Silent (SNP) | VAF 53/446 reads (12%) | catalogued as rs752387000; called by muse, mutect2, varscan2
- AMH | c.1503G>A p.P501= | Silent (SNP) | VAF 44/287 reads (15%) | called by muse, mutect2, varscan2
- CDH20 | c.714C>T p.Y238= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as rs370206160; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.849G>A p.A283= | Silent (SNP) | VAF 23/189 reads (12%) | catalogued as rs138943358; called by muse, mutect2, varscan2
- CIC | c.3096C>T p.Y1032= | Silent (SNP) | VAF 50/558 reads (9%) | catalogued as rs146077012; called by muse, mutect2
- CPNE9 | c.249G>A p.L83= | Silent (SNP) | VAF 24/232 reads (10%) | called by muse, mutect2, varscan2
- DBF4B | c.273C>T p.S91= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV100154545; called by muse, mutect2, varscan2
- EGFL6 | c.24G>A p.A8= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as COSV63635438; called by muse, mutect2, varscan2
- GNAO1 | c.819T>C p.D273= | Silent (SNP) | VAF 25/221 reads (11%) | called by muse, mutect2, varscan2
- HTR3D | c.372C>T p.I124= (on ENST00000382489 / NM_001163646.2; = p.I63= on NM_001145143.1) | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs890133288, COSV100488030; called by muse, mutect2, varscan2
- ITGAE | c.306C>T p.H102= | Silent (SNP) | VAF 14/120 reads (12%) | catalogued as rs780952482, COSV53993644; called by muse, mutect2
- KPNA7 | c.705C>T p.C235= | Silent (SNP) | VAF 47/323 reads (15%) | catalogued as rs577711835; called by muse, mutect2, varscan2
- MESP2 | c.699C>T p.P233= | Silent (SNP) | VAF 37/351 reads (11%) | catalogued as rs778162692; called by muse, mutect2, varscan2
- NLRP4 | c.669G>A p.P223= | Silent (SNP) | VAF 31/251 reads (12%) | catalogued as rs746075034, COSV56707602, COSV56708334; called by muse, mutect2, varscan2
- PCDHB6 | c.855C>T p.D285= | Silent (SNP) | VAF 58/391 reads (15%) | catalogued as rs1459633868; called by muse, mutect2, varscan2
- PPP2R3B | c.1362G>A p.T454= | Silent (SNP) | VAF 41/270 reads (15%) | catalogued as rs764312763; called by muse, mutect2, varscan2
- PRDM12 | c.186C>T p.A62= | Silent (SNP) | VAF 20/190 reads (11%) | called by muse, mutect2, varscan2
- RERE | c.1560C>T p.H520= | Silent (SNP) | VAF 40/344 reads (12%) | catalogued as rs143292179; called by muse, mutect2, varscan2
- RSPH10B2 | c.1575C>T p.T525= | Silent (SNP) | VAF 20/220 reads (9%) | catalogued as rs764853526; called by muse, mutect2
- SDHAF3 | c.75G>A p.P25= | Silent (SNP) | VAF 17/176 reads (10%) | called by muse, mutect2
- SF3B5 | c.159C>T p.F53= | Silent (SNP) | VAF 47/532 reads (9%) | called by muse, mutect2
- SMO | c.1371C>T p.F457= | Silent (SNP) | VAF 16/177 reads (9%) | called by muse, mutect2
- SPEF2 | c.454C>T p.L152= | Silent (SNP) | VAF 7/67 reads (10%) | called by muse, mutect2, varscan2
- TG | c.1863G>A p.T621= | Silent (SNP) | VAF 39/214 reads (18%) | catalogued as rs148739204; called by muse, mutect2, varscan2
- TGFBR3 | c.1572G>A p.V524= | Silent (SNP) | VAF 43/327 reads (13%) | called by muse, mutect2, varscan2
- TMEM163 | c.819C>T p.I273= | Silent (SNP) | VAF 21/189 reads (11%) | catalogued as rs750045704; called by muse, mutect2, varscan2
- TNXB | c.9777C>T p.P3259= (on ENST00000647633; = p.P3012= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/216 reads (13%) | catalogued as rs373994388, COSV64476667; called by muse, mutect2, varscan2
- TRIM7 | c.945T>C p.S315= | Silent (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- AC073310.1 | n.160C>T | RNA (SNP) | VAF 35/337 reads (10%) | catalogued as rs768411526; called by muse, mutect2, varscan2
- AHCY | c.854+9C>T | Intron (SNP) | VAF 71/684 reads (10%) | called by muse, mutect2, varscan2
- AMPH | c.1182+1311A>C | Intron (SNP) | VAF 33/336 reads (10%) | catalogued as COSV57749194; called by muse, mutect2
- H2BP2 | n.1062-335G>A | Intron (SNP) | VAF 100/940 reads (11%) | catalogued as rs587678648; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.7-9T>C | Intron (SNP) | VAF 11/64 reads (17%) | catalogued as rs773972068, COSV61159208; ClinVar: likely benign; called by mutect2, varscan2
- NLRP12 | c.-10C>T | 5'UTR (SNP) | VAF 26/254 reads (10%) | catalogued as rs577347120, COSV60746207; called by muse, mutect2
- TRAPPC2L | c.207-308G>A | Intron (SNP) | VAF 21/175 reads (12%) | catalogued as rs563853558; called by muse, mutect2, varscan2
